Somatic mutation profile of tumor specimen TCGA-EJ-A65F-01A (aliquot TCGA-EJ-A65F-01A-21D-A30X-08) from TCGA case TCGA-EJ-A65F, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Prostate gland; Age at diagnosis: 59.4 years (21,681 days).
Specimen TCGA-EJ-A65F-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 82c09fac-fc02-4b80-b23e-f09b71c20de9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-A65F-10A (Blood Derived Normal), aliquot TCGA-EJ-A65F-10A-01D-A30X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/188406cd-231f-43d2-9d74-f4587090194d

The open-access MAF lists 81 somatic variants for this specimen: 60 protein-altering or splice-affecting, 16 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 16, Splice Site 3, Nonsense Mutation 2, Frame Shift Del 2, In Frame Del 2, In Frame Ins 1, Splice Region 1, Frame Shift Ins 1, Intron 1, 5'Flank 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA5 | c.2681A>T p.K894I | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as COSV67016265; called by muse, mutect2, varscan2
- AC100868.1 | c.1891C>A p.P631T | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.352); catalogued as COSV51840397; called by muse, mutect2, varscan2
- ADGRD1 | c.1260G>C p.W420C | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.749); catalogued as COSV55442109; called by muse, mutect2, varscan2
- ANKLE2 | c.986T>C p.I329T | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.035); catalogued as rs1488868843, COSV61708567; called by muse, mutect2, varscan2
- ATP2B4 | c.2812+1G>A p.X938_splice | Splice Site (SNP) | VAF 11/90 reads (12%) | catalogued as COSV58175995; called by muse, mutect2
- AWAT2 | c.874A>G p.I292V | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.095); catalogued as COSV52143043, COSV99339700; called by muse, mutect2, varscan2
- BAZ2B | c.6298G>A p.V2100I | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.901); catalogued as rs766990267, COSV58598098; called by muse, mutect2, varscan2
- BNC2 | c.2706C>G p.D902E | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.042); catalogued as COSV66163012; called by muse, mutect2, varscan2
- CACNA2D3 | c.2030T>A p.L677Q | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.928); catalogued as COSV55527255; called by muse, mutect2, varscan2
- CCDC148 | c.1016C>A p.T339K | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV51757406; called by muse, mutect2, varscan2
- CDH19 | c.329G>A p.R110Q | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1230780998, COSV100051278, COSV50956087; called by muse, mutect2
- CDYL | c.859T>C p.S287P (on ENST00000328908 / NM_001368125.1; = p.S233P on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV59359133; called by muse, mutect2, varscan2
- CHD7 | c.2819C>T p.P940L | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as rs753887911, CM1413031, COSV71108539; called by muse, mutect2, varscan2
- COL11A1 | c.1570C>T p.R524W | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs771139447, COSV62178322; called by muse, mutect2, varscan2
- CTNNA2 | c.979C>T p.R327W | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780510791, COSV100783486, COSV63557409; called by muse, varscan2
- DSP | c.6008A>G p.E2003G | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as COSV65792132; called by muse, mutect2, varscan2
- ENAH | c.1450G>T p.A484S | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0.119); catalogued as COSV52866719; called by muse, mutect2, varscan2
- EPHA7 | c.2899G>A p.G967R | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs560174275, COSV65178891, COSV65192034; called by muse, mutect2
- FBXW10 | c.520A>T p.I174F | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV57316004; called by mutect2, varscan2
- FRMPD1 | c.2152T>A p.Y718N | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV66699777; called by muse, mutect2, varscan2
- GALNT3 | c.629A>C p.Y210S | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as COSV67061586; called by muse, mutect2, varscan2
- GLI2 | c.4679A>T p.E1560V (on ENST00000361492 / NM_001374353.1; = p.E1577V on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58038340; called by muse, mutect2, varscan2
- GP5 | c.1219T>G p.F407V | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV59878077; called by muse, mutect2, varscan2
- GRIN3A | c.2034G>A p.W678* | Nonsense Mutation (SNP) | VAF 37/148 reads (25%) | catalogued as COSV62452218; called by muse, mutect2, varscan2
- HIPK1 | c.1462C>T p.R488* | Nonsense Mutation (SNP) | VAF 9/59 reads (15%) | catalogued as COSV61246961; called by muse, mutect2, varscan2
- IL13RA1 | c.697A>G p.I233V | Missense Mutation (SNP) | VAF 63/80 reads (79%) | SIFT tolerated (0.07); PolyPhen benign (0.097); catalogued as COSV65426247; called by muse, mutect2, varscan2
- IL21 | c.416G>A p.R139K | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.622); catalogued as COSV52645748, COSV52645762; called by muse, mutect2, varscan2
- IQCD | c.469A>G p.R157G | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55320845; called by muse, mutect2
- IQGAP2 | c.4669G>C p.V1557L | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as COSV57171286; called by muse, mutect2, varscan2
- IRAG2 | c.4186C>T p.L1396F (on ENST00000636465; = p.L441F on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.511); catalogued as COSV57231085; called by muse, mutect2, varscan2
- KCNV1 | c.1347A>T p.E449D | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.696); catalogued as COSV52085455, COSV99819465; called by muse, mutect2, varscan2
- KIFC3 | c.993G>T p.E331D | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV65549617; called by muse, mutect2, varscan2
- KLHL2 | c.1630C>G p.L544V | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.097); catalogued as COSV56975678; called by muse, mutect2
- LIPT1 | c.856C>T p.H286Y | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV60739493; called by muse, mutect2
- LRP4 | c.964G>C p.G322R | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.831); catalogued as COSV66134996; called by muse, mutect2, varscan2
- LRRC3B | c.508G>C p.V170L | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.085); catalogued as COSV67520379, COSV67520662; called by muse, mutect2, varscan2
- MINDY4 | c.349G>C p.V117L | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.097); catalogued as rs750762230, COSV54672831; called by muse, mutect2, varscan2
- MRGPRX1 | c.893C>T p.A298V | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs183845903, COSV57106525; called by muse, mutect2, varscan2
- NEB | c.9051T>A p.S3017R | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.242); catalogued as COSV50951880; called by muse, mutect2, varscan2
- NUP210L | c.1968T>A p.A656= | Splice Region (SNP) | VAF 16/45 reads (36%) | catalogued as COSV55144906; called by muse, mutect2, varscan2
- P3H4 | c.572T>G p.V191G | Missense Mutation (SNP) | VAF 91/303 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV58635955; called by muse, mutect2, varscan2
- PLXNC1 | c.2355A>T p.L785F | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51572893; called by muse, mutect2, varscan2
- PSMD5 | c.924C>G p.D308E | Missense Mutation (SNP) | VAF 9/131 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV52960359; called by muse, mutect2
- RABEP1 | c.1567C>T p.H523Y | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as COSV52584138; called by muse, mutect2, varscan2
- RABGAP1 | c.745C>T p.R249W | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs897382844, COSV58059964; called by muse, mutect2, varscan2
- RPP25L | c.220G>C p.V74L | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as COSV52406931, COSV52408787; called by mutect2, varscan2
- TACC2 | c.6926A>T p.E2309V (on ENST00000334433; = p.E387V on NM_006997.4) | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53279085; called by muse, mutect2, varscan2
- TTN | c.77213T>G p.V25738G (on ENST00000591111; = p.V18314G on NM_003319.4) | Missense Mutation (SNP) | VAF 21/91 reads (23%) | PolyPhen probably damaging (0.948); catalogued as COSV59969079; called by muse, mutect2, varscan2
- UNC13B | c.2410C>G p.H804D | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV65933321; called by muse, mutect2, varscan2
- VRTN | c.367A>T p.M123L | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); catalogued as COSV56439971; called by muse, mutect2
- ZNF287 | c.1571_1573del p.L524del | In Frame Del (DEL) | VAF 18/83 reads (22%) | catalogued as rs768193322; called by pindel, varscan2
- ZNF93 | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.646); catalogued as COSV59374872; called by muse, mutect2, varscan2
- ZNFX1 | c.3476C>A p.T1159N | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65595759; called by muse, mutect2
- ACTN3 | c.1276+3_1276+42del p.X426_splice | Splice Site (DEL) | VAF 9/57 reads (16%) | called by mutect2, pindel
- AMBP | c.604-16_604del p.X202_splice | Splice Site (DEL) | VAF 16/69 reads (23%) | called by mutect2, pindel, varscan2
- HNRNPR | c.1552_1554dup p.R518dup | In Frame Ins (INS) | VAF 6/51 reads (12%) | called by mutect2, pindel
- OR4F6 | c.540_551delinsAAC p.D180_F184delinsET | In Frame Del (DEL) | VAF 23/113 reads (20%) | called by pindel, varscan2*
- OR56A4 | c.269del p.F90Sfs*12 | Frame Shift Del (DEL) | VAF 13/57 reads (23%) | called by mutect2, pindel, varscan2
- SLF2 | c.1859_1860insTA p.L621Nfs*2 | Frame Shift Ins (INS) | VAF 26/98 reads (27%) | called by mutect2, pindel, varscan2
- ZNF536 | c.2267_2297del p.C756Lfs*5 | Frame Shift Del (DEL) | VAF 20/121 reads (17%) | called by mutect2, pindel
- BTBD7 | c.2985T>A p.G995= | Silent (SNP) | VAF 10/134 reads (7%) | catalogued as COSV58284641; called by muse, mutect2
- CDH24 | c.1110G>A p.E370= | Silent (SNP) | VAF 32/93 reads (34%) | catalogued as COSV52974795; called by muse, mutect2, varscan2
- CHD9 | c.624C>T p.V208= | Silent (SNP) | VAF 50/154 reads (32%) | catalogued as COSV68297646; called by muse, mutect2, varscan2
- FAM83A | c.312C>A p.T104= | Silent (SNP) | VAF 38/180 reads (21%) | catalogued as COSV52684731; called by muse, mutect2, varscan2
- FCAMR | c.1527T>C p.L509= (on ENST00000324852 / NM_001170631.2; = p.L242S on NM_032029.4) | Silent (SNP) | VAF 110/223 reads (49%) | catalogued as COSV61367214; called by muse, mutect2, varscan2
- ICAM4 | c.474G>T p.V158= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as COSV53424276; called by muse, mutect2, varscan2
- MAPKAPK2 | c.207C>G p.V69= | Silent (SNP) | VAF 28/56 reads (50%) | catalogued as COSV54315272; called by muse, mutect2, varscan2
- MYH9 | c.2862G>A p.E954= | Silent (SNP) | VAF 6/59 reads (10%) | catalogued as COSV53384065; called by muse, mutect2
- NLRP8 | c.2499G>A p.A833= | Silent (SNP) | VAF 57/168 reads (34%) | catalogued as rs368088277; called by muse, mutect2, varscan2
- SEPTIN3 | c.78G>A p.A26= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as rs759843369, COSV52171504; called by muse, mutect2, varscan2
- SLCO5A1 | c.2229C>T p.A743= | Silent (SNP) | VAF 43/143 reads (30%) | catalogued as rs771544368, COSV52656843; called by muse, mutect2, varscan2
- SPON1 | c.81G>C p.L27= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs1242690206, COSV59959230; called by muse, mutect2
- SS18L1 | c.474C>A p.A158= | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as COSV59209781; called by muse, mutect2, varscan2
- TACR3 | c.760C>T p.L254= | Silent (SNP) | VAF 25/73 reads (34%) | catalogued as COSV59199882; called by muse, mutect2, varscan2
- UNC13C | c.5118A>G p.E1706= | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as COSV52858141; called by muse, mutect2, varscan2
- ZSCAN26 | c.1317G>A p.Q439= (on ENST00000623276 / NM_001111039.2; = p.Q305= on NM_152736.5) | Silent (SNP) | VAF 13/50 reads (26%) | called by mutect2, varscan2
- ADAM12 | c.2113+833C>T | Intron (SNP) | VAF 5/48 reads (10%) | catalogued as COSV64104486; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65505367 del ATGCTTGAAGTACCCCTGGGCTTCTCTTAACATTTAAGCAAGC | 5'Flank (DEL) | VAF 6/66 reads (9%) | called by mutect2, pindel
- CEP295 | chr11:93731015 del AGAT | 3'Flank (DEL) | VAF 30/89 reads (34%) | called by mutect2, pindel, varscan2
- KIR3DX1 | n.908G>A | RNA (SNP) | VAF 40/110 reads (36%) | catalogued as COSV55597619; called by muse, mutect2, varscan2
- TMEM107 | c.*746T>G | 3'UTR (SNP) | VAF 11/40 reads (28%) | catalogued as COSV100328759; called by muse, mutect2, varscan2
